Gene-level copy-number profile of tumor specimen TCGA-V1-A9ZK-01A from TCGA case TCGA-V1-A9ZK, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9ZK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.b56cd120-22ef-460e-896f-fc0dd88fc45d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V1-A9ZK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ab00789d-b902-4d43-b137-b530459c12c5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 78; copy number 1: 9,085; copy number 2: 49,158; copy number 3: 1,411; copy number 4: 12; copy number 6: 74.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V1-A9ZK-01A-11D-A41J-01): tumor purity 0.36, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 78 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:98,576,341–104,406,121, 68 genes (broad region; genes not listed).
- chr5:104,434,772–104,435,499, 1 gene: AC091931.1.
- chr13:83,298,071–84,448,603, 9 genes (within-gene range 0–1): RNU6-67P, AL353688.1, SLITRK1, AL355481.1, VENTXP2, AL590681.1, UBE2D3P4, AL445604.1, AL162493.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 74 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,318,861, 10 genes, copy number 6: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr14:22,040,594–22,502,292, 64 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,798. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
